Somatic mutation profile of tumor specimen TCGA-DV-A4VZ-01A (aliquot TCGA-DV-A4VZ-01A-11D-A25V-10) from TCGA case TCGA-DV-A4VZ, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 53.6 years (19,560 days).
Specimen TCGA-DV-A4VZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d9a92e18-31f5-49c7-822e-713b9a3007e0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DV-A4VZ-10A (Blood Derived Normal), aliquot TCGA-DV-A4VZ-10A-01D-A25V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6560e4d2-2139-4b59-84d3-ef75035c2d79

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 6, Silent 3, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH10 | c.260G>A p.G87E | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); catalogued as COSV52568571, COSV52574764; called by mutect2, varscan2
- DCTN1 | c.2710G>A p.A904T | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100720865; called by muse, mutect2, varscan2
- FLG | c.5693C>T p.S1898L | Missense Mutation (SNP) | VAF 182/513 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs758337721, COSV64238844; called by muse, mutect2, varscan2
- KDR | c.2282C>G p.T761R | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); catalogued as COSV99028722, COSV99816752; called by muse, mutect2, varscan2
- OR2W1 | c.580A>G p.T194A | Missense Mutation (SNP) | VAF 68/192 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV101013896; called by muse, varscan2
- OTOL1 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 58/191 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV100019757, COSV60007631; called by muse, mutect2, varscan2
- ZFPM1 | c.1074_1076del p.T359del | In Frame Del (DEL) | VAF 58/172 reads (34%) | catalogued as rs945209597; called by pindel, varscan2
- H2BC18 | c.192C>T p.N64= | Silent (SNP) | VAF 73/175 reads (42%) | catalogued as COSV58944028; called by muse, mutect2, varscan2
- PYGB | c.930C>T p.R310= | Silent (SNP) | VAF 61/172 reads (35%) | catalogued as COSV99404863; called by muse, mutect2, varscan2
- TTN | c.74712C>T p.V24904= (on ENST00000591111; = p.V17480= on NM_003319.4) | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as COSV100595068; called by muse, mutect2, varscan2
